TCGA case TCGA-RW-A7CZ — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: Michigan University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d1eea093-f349-435f-b8d4-1b40b35503d7

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Extra-adrenal paraganglioma, NOS (the primary disease): ICD-O-3 morphology code: 8693/1; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 73.0 years (26,657 days); Year of diagnosis: 2013; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 422 days (1.2 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Prior primary; Age at diagnosis: 72.3 years (26,394 days); Days to diagnosis: -263 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -263 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 134 days; Disease response: Tumor Free.
- Days to follow up: 422 days (1.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RW-A7CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-RW-A7CZ-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RW-A7CZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RW-A7CZ-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: Extra-adrenal; Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Paraganglioma, Extra-adrenal Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Skin; Other malignancy histological type: Basal cell carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 422 days; disease-specific survival: no event (censored), 422 days; disease-free interval: no event (censored), 422 days; progression-free interval: no event (censored), 422 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RW-A7CZ-01A-11D-A35C-01): tumor purity 0.41, ploidy 3.88, whole-genome doublings 1.
